Somatic mutation profile of tumor specimen TCGA-99-8033-01A (aliquot TCGA-99-8033-01A-11D-2238-08) from TCGA case TCGA-99-8033, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.9 years (27,342 days).
Specimen TCGA-99-8033-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79c5f4d6-a845-4b38-a0e0-f356a19e58ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-99-8033-10A (Blood Derived Normal), aliquot TCGA-99-8033-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2403fa7-e05e-4622-aa92-8d4da98e3dc0

The open-access MAF lists 186 somatic variants for this specimen: 144 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 38, Nonsense Mutation 17, Frame Shift Del 6, Splice Region 2, Frame Shift Ins 2, Splice Site 2, 5'Flank 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58052470; called by muse, mutect2, varscan2
- ABCF1 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV58229497; called by muse, mutect2, varscan2
- ACTRT2 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV65759593; called by muse, mutect2, varscan2
- ADGRV1 | c.12793C>T p.P4265S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1172525838, COSV67987740; called by muse, mutect2, varscan2
- ALDOB | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV66398056; called by muse, mutect2, varscan2
- AMOT | c.2419G>T p.G807C (on ENST00000371959 / NM_001113490.1; = p.G398C on NM_133265.3) | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV59064646; called by muse, mutect2, varscan2
- ANKFN1 | c.35A>G p.K12R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); catalogued as rs1302214992, COSV59450353; called by muse, mutect2, varscan2
- ANKRD27 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 82/452 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV60132656; called by muse, mutect2, varscan2
- ANO2 | c.725A>T p.N242I (on ENST00000356134 / NM_001278597.3; = p.N246I on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV59028044; called by muse, mutect2, varscan2
- APOH | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as COSV52773151; called by muse, mutect2, varscan2
- ARFGEF3 | c.2660G>A p.S887N | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.757); catalogued as COSV52460438; called by muse, mutect2, varscan2
- ATF6 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV63408110; called by muse, mutect2, varscan2
- ATF7 | c.397C>G p.P133A (on ENST00000548446 / NM_001366555.2; = p.P122A on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV60644390; called by muse, mutect2, varscan2
- BCLAF1 | c.2713A>G p.M905V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1432047300, COSV50358343; called by muse, mutect2, varscan2
- BHMT | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV57154728; called by muse, mutect2, varscan2
- BOD1L1 | c.1275G>T p.E425D | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as COSV50019462; called by muse, mutect2, varscan2
- BPNT1 | c.881A>T p.Y294F | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV59040272; called by muse, mutect2
- C10orf88 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV64404059; called by muse, mutect2, varscan2
- CADM1 | c.495C>A p.N165K | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV59013583; called by muse, mutect2
- CARMIL1 | c.2137A>C p.I713L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV61519045; called by muse, mutect2
- CATIP | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs749702307, COSV56823143; called by muse, mutect2, varscan2
- CATSPER1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV56411436; called by muse, mutect2, varscan2
- CD163 | c.706T>C p.W236R | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63133702; called by muse, mutect2, varscan2
- CD1A | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.253); catalogued as COSV56862363; called by muse, mutect2
- CD1D | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as COSV100939592; called by muse, mutect2
- CDHR1 | c.1736G>A p.S579N | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200776781, COSV60563432; called by muse, mutect2, varscan2
- CDHR2 | c.2749A>T p.T917S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.057); catalogued as COSV99991557; called by muse, mutect2
- CEBPZ | c.1084A>T p.K362* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV50017888; called by muse, mutect2, varscan2
- CELF4 | c.515T>C p.F172S | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58456329; called by muse, mutect2, varscan2
- CGREF1 | c.462_463insA p.P155Tfs*20 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as COSV99565147; called by mutect2, pindel, varscan2
- CHD7 | c.7847T>G p.L2616R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV71112016; called by muse, mutect2, varscan2
- CNTNAP5 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70473113; called by muse, mutect2, varscan2
- COL11A1 | c.2806C>A p.P936T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV62186492; called by muse, varscan2
- COL25A1 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV101211416; called by muse, mutect2, varscan2
- CPA3 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.542); catalogued as COSV56045655; called by muse, mutect2, varscan2
- CRAMP1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as COSV51963213; called by muse, varscan2
- CREBBP | c.5269G>T p.G1757C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV52127672; called by muse, mutect2, varscan2
- CROT | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.397); catalogued as COSV100519510; called by muse, mutect2, varscan2
- CSMD1 | c.9475C>A p.P3159T (on ENST00000520002; = p.P3158T on NM_033225.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs763939958, COSV59337512; called by muse, mutect2, varscan2
- DCAF12L2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63582303, COSV63584620; called by muse, mutect2, varscan2
- DENND5B | c.3715G>T p.A1239S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.357); catalogued as rs747314854, COSV100171432, COSV60905604; called by muse, mutect2
- DOCK4 | c.5308C>G p.L1770V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV70238519; called by muse, mutect2
- DZIP3 | c.1396G>C p.D466H | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV64312512; called by muse, mutect2, varscan2
- EBF3 | c.1783C>A p.P595T (on ENST00000355311 / NM_001375392.1; = p.P550T on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV62476368; called by muse, mutect2, varscan2
- EBF3 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV62476378; called by muse, mutect2, varscan2
- EFCAB1 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV50618560; called by muse, mutect2, varscan2
- EXOC4 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1378416459, COSV54103390; called by muse, mutect2
- F13B | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803284, COSV66372257; called by muse, mutect2, varscan2
- FAT2 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV55821877; called by muse, mutect2
- FBN2 | c.1851T>C p.D617= | Splice Region (SNP) | VAF 17/136 reads (13%) | catalogued as COSV52520827; called by muse, mutect2, varscan2
- FLI1 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55644922, COSV99857700; called by muse, varscan2
- FOXN2 | c.704-2A>C p.X235_splice | Splice Site (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100489196; called by muse, mutect2, varscan2
- FZD10 | c.1121G>C p.R374T | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.348); catalogued as COSV57474168; called by muse, mutect2, varscan2
- GON4L | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55195791, COSV99674730; called by muse, mutect2, varscan2
- GYPA | c.240G>C p.R80S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV51629185; called by muse, mutect2, varscan2
- HAVCR1 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 55/520 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as rs114193906, COSV59400630; called by muse, mutect2, varscan2
- HHIPL1 | c.1560C>G p.I520M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58091417, COSV58093333; called by muse, mutect2, varscan2
- HMCN1 | c.14896G>T p.G4966* | Nonsense Mutation (SNP) | VAF 45/141 reads (32%) | catalogued as rs1184521225, COSV54909165; called by muse, mutect2, varscan2
- IDE | c.2663C>A p.A888E | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56424448; called by muse, mutect2, varscan2
- IDNK | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV52891826; called by muse, mutect2, varscan2
- IGF2BP1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as COSV51732548; called by muse, mutect2, varscan2
- ITGAD | c.3466C>T p.P1156S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV54932180, COSV99791253; called by muse, mutect2, varscan2
- KCNAB3 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV58050426; called by muse, mutect2, varscan2
- KEAP1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50297634; called by muse, mutect2, varscan2
- KIAA1522 | c.364G>A p.A122T (on ENST00000373480 / NM_001198972.2; = p.A181T on NM_020888.3) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.135); catalogued as COSV53865237; called by muse, mutect2
- KIF26A | c.3431G>T p.G1144V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59467575; called by muse, mutect2, varscan2
- KSR2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV60381573; called by muse, mutect2, varscan2
- LAMA3 | c.3025A>G p.I1009V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs371860543; called by muse, mutect2, varscan2
- LPCAT1 | c.1157A>C p.D386A | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV52038790; called by muse, mutect2, varscan2
- LRP1 | c.4904G>A p.R1635Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs766682074, COSV54503077; called by muse, mutect2, varscan2
- MAT1A | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV64746010; called by muse, mutect2, varscan2
- MAZ | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.414); catalogued as rs1555501541, COSV50715712; called by muse, mutect2
- MCM6 | c.1886A>T p.E629V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51467116; called by muse, mutect2, varscan2
- MKNK2 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51733115; called by muse, mutect2, varscan2
- MRPS9 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV51520166; called by muse, mutect2, varscan2
- MTMR4 | c.2485A>T p.S829C | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.215); catalogued as COSV60201169; called by muse, mutect2, varscan2
- MYH11 | c.5528C>A p.S1843* | Nonsense Mutation (SNP) | VAF 25/125 reads (20%) | catalogued as COSV55556983; called by muse, mutect2, varscan2
- OFD1 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100406907; called by muse, mutect2, varscan2
- OLFM4 | c.70del p.D24Mfs*37 | Frame Shift Del (DEL) | VAF 40/211 reads (19%) | catalogued as COSV99524208; called by mutect2, pindel, varscan2
- OR10Z1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63524979; called by muse, mutect2, varscan2
- OR3A3 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52167706; called by muse, mutect2, varscan2
- OR4A47 | c.288G>T p.M96I | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); catalogued as rs1189793015, COSV71445025; called by muse, mutect2, varscan2
- OR5D13 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1458817654, COSV100686871, COSV100686945, COSV62333789; called by muse, mutect2, varscan2
- OR5M3 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56567235; called by muse, mutect2, varscan2
- OR8H2 | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV57945409; called by muse, mutect2, varscan2
- OR8U1 | c.504T>A p.Y168* | Nonsense Mutation (SNP) | VAF 76/632 reads (12%) | catalogued as COSV100163898; called by muse, mutect2, varscan2
- PCDH11X | c.1712C>A p.T571N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53475571; called by muse, mutect2, varscan2
- PCDHB4 | c.2039C>A p.A680D | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.288); catalogued as COSV52023600; called by muse, mutect2, varscan2
- PDGFRA | c.2734G>T p.G912W | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57269545; called by muse, mutect2, varscan2
- PEMT | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99703084; called by muse, mutect2, varscan2
- PEX1 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV50401396; called by muse, mutect2, varscan2
- PGM2L1 | c.1642G>T p.V548L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV53347599; called by muse, mutect2, varscan2
- PLXNA4 | c.5195C>A p.P1732Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV58134615; called by muse, mutect2, varscan2
- POLRMT | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV73933320; called by muse, mutect2, varscan2
- POSTN | c.354C>G p.D118E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.403); catalogued as COSV101123317, COSV101123557, COSV65713373; called by muse, mutect2, varscan2
- PRPF19 | c.1125G>T p.K375N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV57128292; called by muse, mutect2, varscan2
- PRSS58 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV73488717; called by muse, mutect2, varscan2
- PTPRB | c.5701G>A p.V1901M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54243698; called by muse, mutect2, varscan2
- RBM15 | c.2179C>T p.R727* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as COSV63923701; called by muse, mutect2, varscan2
- RP1L1 | c.2797G>T p.G933C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV66756420; called by muse, mutect2, varscan2
- RPAP1 | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV100427123; called by muse, mutect2, varscan2
- RPAP1 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100427125; called by muse, mutect2, varscan2
- S100A7 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs756055414, COSV64193448; called by muse, mutect2, varscan2
- SEPTIN14 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV66428372; called by muse, mutect2, varscan2
- SLC45A2 | c.1535C>G p.S512C | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56872615; called by muse, mutect2
- SLC6A15 | c.1310A>T p.Q437L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs746624989, COSV99880742; called by muse, mutect2, varscan2
- SLC6A15 | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); catalogued as COSV57025061; called by muse, mutect2, varscan2
- SNX14 | c.1270G>T p.E424* (on ENST00000314673 / NM_001350535.1; = p.E380* on NM_020468.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV59013334; called by muse, mutect2, varscan2
- SP100 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV50984260; called by muse, mutect2, varscan2
- SPAM1 | c.1394T>C p.I465T | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV56142085; called by muse, mutect2, varscan2
- SPIC | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as COSV100162948; called by muse, mutect2
- ST6GALNAC5 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | PolyPhen probably damaging (0.951); catalogued as COSV100602689; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.264C>A p.P88= | Splice Region (SNP) | VAF 5/47 reads (11%) | catalogued as COSV59566355; called by muse, mutect2, varscan2
- STON1 | c.939G>T p.Q313H | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV59132104; called by muse, mutect2
- TASOR2 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as rs1564320409, COSV60167979; called by muse, mutect2, varscan2
- TDRD7 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62429869; called by muse, mutect2, varscan2
- TGM7 | c.828C>A p.Y276* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV101476852; called by muse, varscan2
- TINAGL1 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54699261; called by muse, varscan2
- TMEM125 | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101443199; called by muse, mutect2, varscan2
- TMEM209 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV52833686; called by muse, mutect2, varscan2
- TMPRSS11F | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100678518, COSV100678738; called by muse, mutect2, varscan2
- TMPRSS11F | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100678521, COSV62467875; called by muse, mutect2, varscan2
- TRIM9 | c.474C>A p.Y158* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV53619007; called by mutect2, varscan2
- TSC2 | c.3132-1G>C p.X1044_splice | Splice Site (SNP) | VAF 22/91 reads (24%) | catalogued as rs45443096, CS078615, CS993996, COSV54768219; ClinVar: not provided; called by muse, mutect2, varscan2
- TSLP | c.8C>G p.P3R | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61291806; called by muse, mutect2, varscan2
- UBE2O | c.934A>G p.S312G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV60064458; called by muse, mutect2, varscan2
- WDR72 | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV64748711; called by muse, mutect2
- ZBED1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.97); catalogued as COSV58134916; called by muse, mutect2
- ZDBF2 | c.4788A>T p.Q1596H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV65627033; called by muse, mutect2
- ZFHX4 | c.8711T>C p.I2904T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as rs771779590, COSV51441298; called by muse, mutect2, varscan2
- ZFP30 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63622733; called by muse, mutect2, varscan2
- ZNF479 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV100482733; called by muse, mutect2, varscan2
- ZNF536 | c.2533C>A p.L845I | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.491); catalogued as rs370323894, COSV62821993; called by muse, mutect2, varscan2
- ZNF570 | c.712A>T p.R238* | Nonsense Mutation (SNP) | VAF 32/151 reads (21%) | catalogued as COSV57579510; called by muse, mutect2, varscan2
- ZNF624 | c.2096A>G p.N699S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs903682558, COSV60940352; called by muse, mutect2, varscan2
- ZP4 | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63912403, COSV63913550; called by muse, mutect2, varscan2
- IGHM | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- LCE1D | c.293del p.G98Afs*? | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- NINL | c.786_787del p.F263Qfs*3 | Frame Shift Del (DEL) | VAF 26/148 reads (18%) | called by pindel, varscan2
- PCSK5 | c.1246del p.V416Sfs*9 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by pindel, varscan2
- SH3TC1 | c.2848del p.L950Cfs*194 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.1248_1249insGC p.L417Afs*4 | Frame Shift Ins (INS) | VAF 15/112 reads (13%) | called by mutect2, pindel, varscan2
- XKR4 | c.1843_1844delinsT p.L616Sfs*6 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | called by pindel, varscan2*
- ABL1 | c.897G>A p.V299= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV59333755; called by muse, mutect2, varscan2
- ADAM15 | c.1497G>A p.Q499= | Silent (SNP) | VAF 8/214 reads (4%) | catalogued as COSV55127661; called by muse, mutect2
- ADAMTS18 | c.585G>T p.A195= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV51401324; called by muse, mutect2, varscan2
- ASB17 | c.111G>A p.Q37= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1393320692, COSV52410769; called by muse, mutect2
- CDH9 | c.1107G>T p.V369= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as COSV50251154; called by muse, mutect2, varscan2
- CLEC4F | c.501G>A p.Q167= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs782310629, COSV55479945; called by muse, mutect2, varscan2
- DLG5 | c.1947G>T p.P649= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100967932, COSV64948466; called by muse, varscan2
- ERN1 | c.729C>T p.I243= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV70502742; called by muse, mutect2, varscan2
- ESR1 | c.6C>A p.T2= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV52793322; called by muse, mutect2, varscan2
- FGF13 | c.498C>G p.G166= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as COSV59546489, COSV59547122; called by muse, mutect2, varscan2
- FMN2 | c.4332C>A p.I1444= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs764305551, COSV60426950, COSV60434723; called by muse, mutect2, varscan2
- FYCO1 | c.1569A>G p.A523= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV56116912; called by muse, mutect2, varscan2
- JAK2 | c.2481A>T p.I827= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV67621068; called by muse, mutect2, varscan2
- KCNK3 | c.1008C>T p.S336= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1173148813, COSV57192986; called by muse, mutect2, varscan2
- KLHL4 | c.243C>A p.A81= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100909540; called by muse, mutect2
- LRP2 | c.11355G>A p.G3785= | Silent (SNP) | VAF 12/191 reads (6%) | catalogued as COSV55558339; called by muse, mutect2
- MASP1 | c.1416G>A p.Q472= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV56224539; called by muse, mutect2, varscan2
- NDST3 | c.1161C>A p.P387= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV56615388, COSV56621261; called by muse, mutect2, varscan2
- OR2M2 | c.816G>A p.K272= | Silent (SNP) | VAF 41/243 reads (17%) | catalogued as COSV62898607; called by muse, mutect2, varscan2
- PLEC | c.13665C>T p.D4555= (on ENST00000322810 / NM_201380.4; = p.D4445= on NM_000445.5) | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs782213390, COSV59649706; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEKHO2 | c.621C>T p.T207= | Silent (SNP) | VAF 44/180 reads (24%) | catalogued as rs564254491, COSV60262282; called by muse, mutect2, varscan2
- PTPRC | c.2592C>A p.I864= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV61413940; called by muse, mutect2, varscan2
- QSOX1 | c.1098T>C p.I366= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV62580750; called by muse, mutect2, varscan2
- RICTOR | c.3405G>A p.T1135= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as rs764024676, COSV57123933; called by muse, mutect2
- RPS27A | c.393T>C p.F131= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as rs137921682, COSV55052009; called by muse, mutect2, varscan2
- RPS6KB1 | c.1542C>T p.I514= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV56677626; called by muse, mutect2, varscan2
- RYR1 | c.2454G>A p.E818= | Silent (SNP) | VAF 35/183 reads (19%) | catalogued as rs1227127709, COSV100615673; called by muse, mutect2, varscan2
- RYR1 | c.2455C>A p.R819= | Silent (SNP) | VAF 35/188 reads (19%) | catalogued as CM081776, COSV100615674, COSV100616994; called by muse, mutect2, varscan2
- S100PBP | c.501G>A p.S167= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs12092326; called by muse, mutect2, varscan2
- SCRN2 | c.288C>T p.G96= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as COSV51636220; called by muse, mutect2, varscan2
- SLC45A1 | c.747C>T p.G249= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs769241812, COSV57096412; called by muse, mutect2, varscan2
- SLC4A5 | c.2697C>T p.S899= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs760412943, COSV100697368, COSV61028895; called by muse, mutect2, varscan2
- SRSF11 | c.1098C>T p.S366= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV63937071; called by muse, mutect2, varscan2
- TNFSF13 | c.510G>C p.L170= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV53432888; called by muse, mutect2, varscan2
- TPO | c.912C>T p.L304= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV61103852; called by muse, mutect2, varscan2
- VIT | c.1602C>A p.I534= (on ENST00000389975 / NM_001177969.1; = p.I549= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV101007381; called by muse, mutect2, varscan2
- ZNF107 | c.609T>C p.L203= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as rs1562845855, COSV61329436; called by muse, mutect2
- ZNF99 | c.378C>T p.H126= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs376866838; called by muse, mutect2, varscan2
- ADGRA1 | chr10:133084925 C>A | 5'Flank (SNP) | VAF 27/100 reads (27%) | catalogued as COSV100811020; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668268 C>A | 5'Flank (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- AMPD2 | c.-128G>A | 5'UTR (SNP) | VAF 18/78 reads (23%) | catalogued as COSV56648454; called by muse, mutect2, varscan2
- GCNT2 | c.926-34758G>T | Intron (SNP) | VAF 21/102 reads (21%) | catalogued as COSV99399281; called by muse, mutect2, varscan2
